Somatic mutation profile of tumor specimen MP2PRT-PAPJFZ-TMP1-A (aliquot MP2PRT-PAPJFZ-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPJFZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,112 days).
Specimen MP2PRT-PAPJFZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5cbd1e9-f43a-44d1-8695-02b53bca9f4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPJFZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPJFZ-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3077cf96-a6dc-4092-9a1c-4f18396c3cf2

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 70/250 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD62 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs1009995057, COSV100019157; called by muse, varscan2
- DOCK3 | c.4432C>T p.R1478C | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1022418525; called by muse, mutect2, varscan2
- NPAS2 | c.366G>A p.S122= | Splice Region (SNP) | VAF 43/173 reads (25%) | catalogued as rs768121019; called by muse, mutect2, varscan2
- TENM3 | c.5408C>T p.T1803M | Missense Mutation (SNP) | VAF 116/364 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs780877206, COSV101305369; called by muse, mutect2, varscan2
- TRAPPC10 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs193063951; called by muse, mutect2, varscan2
- ZMIZ2 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 85/286 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs758713337, COSV54808578, COSV54810303; called by muse, mutect2, varscan2
- CDHR4 | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 133/472 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CPXM1 | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 97/325 reads (30%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- FOXD3 | c.792G>A p.A264= | Silent (SNP) | VAF 164/502 reads (33%) | called by muse, mutect2, varscan2
- PTGDS | c.384C>T p.Y128= | Silent (SNP) | VAF 96/333 reads (29%) | catalogued as rs373555075, COSV56401721; called by muse, mutect2, varscan2
- SCARA5 | c.1311C>T p.R437= | Silent (SNP) | VAF 145/517 reads (28%) | catalogued as rs770079465, COSV61572071; called by muse, mutect2, varscan2
